Somatic mutation profile of tumor specimen TCGA-FA-A6HN-01A (aliquot TCGA-FA-A6HN-01A-11D-A31X-10) from TCGA case TCGA-FA-A6HN, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 74.0 years (27,025 days).
Specimen TCGA-FA-A6HN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 006acd82-56f0-435c-af87-77e03eebf356.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FA-A6HN-10A (Blood Derived Normal), aliquot TCGA-FA-A6HN-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8506ac6-763d-40d6-aa6d-04472e60261a

The open-access MAF lists 211 somatic variants for this specimen: 144 protein-altering or splice-affecting, 64 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 64, Frame Shift Del 9, Nonsense Mutation 8, In Frame Del 4, Splice Region 2, Frame Shift Ins 2, 3'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH15 | c.3316C>T p.R1106* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs202033121, CM094636; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STAT3 | c.1982A>T p.D661V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV52886283; called by muse, mutect2, varscan2
- A2M | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59392728; called by muse, mutect2, varscan2
- ABCA10 | c.2730C>A p.F910L | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99288173; called by muse, mutect2, varscan2
- ACADM | c.1258A>G p.K420E | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100897615; called by muse, mutect2, varscan2
- ACTB | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV59317525, COSV59321570; called by muse, mutect2, varscan2
- ADGRL2 | c.1200G>T p.V400= | Splice Region (SNP) | VAF 25/113 reads (22%) | catalogued as COSV99587788; called by muse, mutect2, varscan2
- AIFM2 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as rs764906460, COSV57158597; called by muse, mutect2, varscan2
- AKAP17A | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100002028; called by muse, mutect2, varscan2
- ALX3 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); catalogued as rs750826128, COSV100873873; called by muse, mutect2, varscan2
- ANK2 | c.11593G>A p.D3865N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.705); catalogued as COSV100000487; called by muse, mutect2, varscan2
- ANXA11 | c.130A>T p.T44S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV55417970; called by muse, mutect2, varscan2
- ARHGAP21 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs780035071, COSV100255958; called by muse, mutect2, varscan2
- ATF4 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148038848; called by muse, mutect2, varscan2
- BTBD9 | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs373363401; called by muse, mutect2, varscan2
- C1S | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.657); catalogued as COSV100196446; called by muse, mutect2, varscan2
- CCDC170 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99498257; called by muse, varscan2
- CCND2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV99714099; called by muse, mutect2, varscan2
- CD70 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 30/150 reads (20%) | catalogued as rs777583938, COSV99835549; called by muse, varscan2
- CHD5 | c.3419A>T p.N1140I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV99312975; called by muse, mutect2, varscan2
- CXCR4 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99602693; called by muse, mutect2, varscan2
- CYB5R4 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV100859458; called by muse, mutect2, varscan2
- DGKI | c.3023G>T p.R1008L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV55969556; called by muse, mutect2, varscan2
- DUSP2 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV99997025, COSV99997112; called by muse, mutect2, varscan2
- DYNC2I2 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as rs889524167, COSV100823365; called by muse, mutect2, varscan2
- EFHC1 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV100931928; called by muse, mutect2, varscan2
- EHD1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.089); catalogued as rs1201657003, COSV57735430; called by muse, mutect2
- EIF2B5 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.203); catalogued as rs755170852, COSV99889104; called by muse, mutect2, varscan2
- EIF4A2 | c.78C>G p.S26R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100125381; called by muse, varscan2
- EPHB1 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV101212870; called by muse, mutect2, varscan2
- ESPN | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs201251427, COSV100911366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCG | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs955462060, COSV100734066; called by muse, mutect2, varscan2
- FPGT | c.427A>C p.I143L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100907095, COSV63841679; called by muse, mutect2, varscan2
- FUT4 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV100708029; called by muse, mutect2, varscan2
- GAS6 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100581264; called by muse, mutect2, varscan2
- GDI1 | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV99340957; called by muse, mutect2, varscan2
- GPR34 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs761720270, COSV100586937; called by muse, mutect2, varscan2
- H1-2 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as rs370479531, COSV59189555; called by muse, mutect2, varscan2
- H1-2 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV59193253; called by muse, varscan2
- H1-3 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs1431078707, COSV99768669; called by muse, mutect2, varscan2
- H1-3 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV55096844, COSV99768672; called by muse, varscan2
- H1-3 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs760334048, COSV55098323; called by muse, varscan2
- H2AC11 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as rs201426448, COSV60363032; called by muse, mutect2, varscan2
- H2AC15 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.774); catalogued as rs772108612, COSV57585618, COSV57586179; called by muse, mutect2, varscan2
- H2AC17 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100377538; called by muse, mutect2, varscan2
- H2BC13 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs1411002200, COSV100704332; called by muse, mutect2, varscan2
- H2BC18 | c.372C>A p.S124R | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100516060; called by muse, mutect2, varscan2
- H2BC21 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV100479756, COSV58612104; called by muse, mutect2, varscan2
- H2BC8 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); catalogued as COSV55126183; called by muse, mutect2
- H4-16 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100797626; called by muse, mutect2, varscan2
- H4C6 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs778148505, COSV66685691; called by muse, mutect2, varscan2
- H4C8 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV99175465; called by muse, mutect2, varscan2
- HEMK1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV99231616; called by muse, mutect2, varscan2
- HIF3A | c.1526C>T p.P509L (on ENST00000377670 / NM_152795.4; = p.P440L on NM_022462.4) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs1342294364, COSV52205175, COSV99355625; called by muse, mutect2, varscan2
- HMCN1 | c.8108C>A p.S2703Y | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99626162; called by muse, mutect2, varscan2
- HNRNPD | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100002796; called by mutect2, varscan2
- HTR1B | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100885365; called by muse, mutect2, varscan2
- IER3 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV99458110; called by muse, varscan2
- IGKC | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773475625; called by muse, mutect2, varscan2
- IGKJ4 | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 15/117 reads (13%) | PolyPhen probably damaging (0.958); catalogued as rs187905157; called by muse, varscan2
- IL2RA | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs267602536, COSV99906589; called by muse, mutect2, varscan2
- IRF4 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66705946; called by muse, mutect2, varscan2
- ISLR2 | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100679461; called by muse, mutect2
- JMJD7-PLA2G4B | c.2840C>A p.T947K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV100310968; called by muse, mutect2, varscan2
- KCNK3 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.117); catalogued as COSV100256722; called by muse, mutect2, varscan2
- KCNU1 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1219795481, COSV101299050; called by muse, mutect2
- KLF2 | c.824G>A p.S275N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs1204502415, COSV50179841, COSV99934120; called by muse, varscan2
- KRTAP5-2 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.354); catalogued as COSV101295071, COSV101295127; called by muse, mutect2, varscan2
- LGALS8 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV99436341; called by muse, mutect2, varscan2
- LINGO4 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100561863; called by muse, mutect2
- LIPN | c.1142A>G p.D381G | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101356215; called by muse, mutect2, varscan2
- LRRFIP2 | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs773335626, COSV100368262; called by muse, mutect2, varscan2
- MGA | c.2923C>T p.Q975* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99579118; called by muse, mutect2, varscan2
- MUC16 | c.15190C>A p.L5064I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.135); catalogued as COSV101198935; called by muse, mutect2, varscan2
- MYC | c.524G>A p.S175N (on ENST00000377970; = p.S190N on NM_002467.6) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.903); catalogued as COSV52367488, COSV99419768; called by muse, mutect2, varscan2
- NAT8L | c.540C>T p.P180= | Splice Region (SNP) | VAF 17/97 reads (18%) | catalogued as rs376253416; called by muse, mutect2, varscan2
- NFKB2 | c.743T>A p.L248Q | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99192275; called by muse, mutect2, varscan2
- NFKBIA | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV53751616; called by muse, varscan2
- NOX4 | c.1727C>A p.S576Y | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV99630024; called by muse, mutect2, varscan2
- OR13C5 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 50/396 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV101053048; called by muse, mutect2
- OR51M1 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV100150178; called by muse, mutect2, varscan2
- OSBPL10 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.324); catalogued as COSV100824385; called by muse, varscan2
- PARD3 | c.2566G>A p.G856S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.576); catalogued as COSV100400606; called by muse, mutect2, varscan2
- PAX5 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV100814124; called by muse, mutect2, varscan2
- PCDHGA12 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.077); catalogued as COSV52754675; called by muse, mutect2, varscan2
- PIK3C2A | c.1594A>C p.K532Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV99790412; called by muse, mutect2, varscan2
- PLD2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs752746653, COSV99562164; called by muse, mutect2, varscan2
- PLD6 | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100387576; called by muse, mutect2, varscan2
- PLG | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100368965; called by muse, mutect2, varscan2
- PPFIA2 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs370246827; called by muse, mutect2, varscan2
- PRCC | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99618538; called by muse, mutect2, varscan2
- PRMT9 | c.383T>G p.V128G | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100482061; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1234G>C p.D412H (on ENST00000352766; = p.D333H on NM_181334.5) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.525); catalogued as COSV100424089; called by muse, mutect2, varscan2
- PSMB5 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as COSV100557297; called by muse, mutect2, varscan2
- PTPN6 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV100016987; called by muse, mutect2, varscan2
- RGS7 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV100465833; called by muse, mutect2, varscan2
- RGS9 | c.1751G>A p.R584K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV99287247; called by muse, mutect2
- RIMS2 | c.4639G>C p.E1547Q (on ENST00000666250 / NM_001348490.2; = p.E1118Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99164726; called by muse, mutect2, varscan2
- RPL8 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs11539889, COSV99369819; called by muse, mutect2
- RXFP2 | c.2241C>G p.D747E | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV100034140; called by muse, mutect2, varscan2
- SCRN2 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99274007; called by muse, mutect2, varscan2
- SEMA3D | c.1970A>G p.K657R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99406197; called by muse, mutect2, varscan2
- SIPA1 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100425765; called by muse, mutect2, varscan2
- SLC12A6 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1255379283, COSV100825231; called by muse, mutect2, varscan2
- SLC16A7 | c.786del p.F262Lfs*39 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | catalogued as COSV53899988; called by mutect2, pindel, varscan2
- SLC35F2 | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99758537; called by muse, mutect2, varscan2
- SMC4 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.524); catalogued as COSV61005697; called by muse, mutect2, varscan2
- SNX1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV99976011; called by muse, mutect2, varscan2
- SOWAHD | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs373940647, COSV100673124; called by muse, mutect2, varscan2
- SPTLC3 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs773287063, COSV100983005; called by muse, mutect2, varscan2
- SSTR4 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs758666610, COSV99658472; called by muse, mutect2, varscan2
- SYNE1 | c.11898C>G p.H3966Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV99557502; called by muse, mutect2, varscan2
- SYNPR | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.636); catalogued as COSV55725134; called by muse, mutect2, varscan2
- TAF1B | c.511C>G p.H171D | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV99721938; called by muse, mutect2, varscan2
- TAF5L | c.988A>C p.N330H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99272863; called by muse, mutect2, varscan2
- TAGAP | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs779668504, COSV100487323; called by muse, mutect2, varscan2
- TFAP2D | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as rs201424626, COSV50427407; called by muse, mutect2, varscan2
- TMEM132A | c.1199T>C p.I400T (on ENST00000453848 / NM_178031.3; = p.I401T on NM_017870.4) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99134390; called by muse, mutect2, varscan2
- TNFRSF8 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99821234; called by muse, mutect2, varscan2
- TOGARAM1 | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100753030; called by muse, mutect2, varscan2
- TRIM24 | c.1591C>T p.L531F (on ENST00000343526 / NM_015905.3; = p.L497F on NM_003852.4) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.109); catalogued as COSV100630774; called by muse, mutect2, varscan2
- TRPM6 | c.2749G>C p.A917P | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100665847; called by muse, mutect2, varscan2
- UCN | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs753655772, COSV99274234; called by muse, mutect2
- ZC2HC1A | c.943T>C p.C315R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99803871; called by muse, mutect2, varscan2
- ZNF208 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.356); catalogued as rs202182420, COSV101236922; called by muse, mutect2
- ZNF367 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100930839; called by muse, varscan2
- ZNF474 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99682062; called by muse, mutect2, varscan2
- ZNF804B | c.359A>C p.E120A | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100301547; called by muse, mutect2, varscan2
- ZNF846 | c.1025A>G p.E342G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.178); catalogued as COSV101194280; called by muse, mutect2, varscan2
- CD68 | c.1023C>G p.F341L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2
- CUBN | c.9686del p.N3229Mfs*32 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- EEF2 | c.945_959del p.E317_I321del | In Frame Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel, varscan2
- EHD1 | c.276del p.T93Pfs*111 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- GPR25 | c.988_1014del p.A330_S338del | In Frame Del (DEL) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- H1-2 | c.485_504del p.A162Efs*4 | Frame Shift Del (DEL) | VAF 11/123 reads (9%) | called by mutect2, pindel
- H1-2 | c.143_144dup p.A49Wfs*15 | Frame Shift Ins (INS) | VAF 9/63 reads (14%) | called by pindel, varscan2
- H3C7 | c.354_364del p.T119Qfs*? | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | called by pindel, varscan2
- IGHE | c.920_934del p.P307_M311del | In Frame Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel
- JUNB | c.88_97del p.H30Nfs*3 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- JUNB | c.514_539del p.V172Rfs*203 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel
- KRTAP5-3 | c.185dup p.S63Lfs*71 | Frame Shift Ins (INS) | VAF 15/104 reads (14%) | called by mutect2, pindel, varscan2
- MAZ | c.951_959del p.K317_D320delinsN | In Frame Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- NFKBIA | c.642del p.C215Vfs*23 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- PCDH1 | c.837del p.K279Nfs*17 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- ABCC10 | c.177C>T p.I59= (on ENST00000372530 / NM_001198934.2; = p.I16= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV55091734; called by muse, mutect2, varscan2
- ADAM9 | c.1248C>A p.S416= | Silent (SNP) | VAF 41/182 reads (23%) | catalogued as COSV101166049; called by muse, mutect2, varscan2
- AKAP8 | c.477G>A p.G159= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99511796; called by muse, mutect2, varscan2
- AL645922.1 | c.3054G>A p.V1018= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as rs553118090, COSV54960147; ClinVar: likely benign / benign; called by muse, mutect2
- ANKS6 | c.2298C>A p.G766= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100782244; called by muse, mutect2, varscan2
- BHLHE41 | c.75C>T p.S25= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV99658229; called by muse, mutect2, varscan2
- BMP15 | c.1164T>C p.S388= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV99399300; called by muse, mutect2, varscan2
- BRAP | c.1677G>A p.E559= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100554036; called by muse, mutect2, varscan2
- BRS3 | c.936C>T p.T312= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV101036494; called by muse, mutect2, varscan2
- CA4 | c.33C>T p.S11= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99958208, COSV99958370; called by mutect2, varscan2
- CDK13 | c.363C>T p.F121= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1423812492, COSV99475262; called by muse, mutect2, varscan2
- CLK1 | c.852G>A p.L284= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100362193; called by muse, mutect2, varscan2
- CORO1A | c.555C>T p.S185= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs745531321, COSV99531905; called by muse, mutect2, varscan2
- DOCK9 | c.3753G>A p.S1251= (on ENST00000376460 / NM_001366676.2; = p.S1252= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs766910695, COSV100238459; called by muse, mutect2, varscan2
- DOHH | c.606C>T p.S202= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99170994; called by muse, mutect2
- EIF4A2 | c.153C>T p.Y51= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs763616993, COSV60626748; called by muse, varscan2
- GADD45B | c.120G>A p.V40= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs544016078, COSV99298010; called by muse, mutect2, varscan2
- GTF2IRD2 | c.25C>T p.L9= | Silent (SNP) | VAF 76/534 reads (14%) | called by muse, mutect2, varscan2
- GZMM | c.438C>T p.S146= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV99198815; called by muse, mutect2, varscan2
- H2AC6 | c.105C>A p.L35= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100019813; called by muse, mutect2, varscan2
- H2BC15 | c.135G>A p.V45= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV100356928; called by muse, mutect2, varscan2
- H2BC21 | c.318G>A p.E106= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV100479753; called by muse, mutect2, varscan2
- H2BC4 | c.363G>A p.K121= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV100019812; called by muse, mutect2, varscan2
- H3C11 | c.219G>A p.R73= | Silent (SNP) | VAF 56/144 reads (39%) | catalogued as COSV100137779; called by muse, mutect2, varscan2
- H3C7 | c.328C>T p.L110= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs748809291, COSV99769042; called by muse, varscan2
- H4C9 | c.195C>T p.N65= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as rs1434983275, COSV100574877; called by muse, mutect2, varscan2
- HIBADH | c.81C>T p.S27= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as rs1562665843, COSV99606996; called by muse, mutect2, varscan2
- IGHM | c.1192C>T p.L398= | Silent (SNP) | VAF 19/98 reads (19%) | called by muse, varscan2
- IGHV2-70 | c.90G>A p.L30= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as rs564942249; called by muse, mutect2, varscan2
- IRS1 | c.9C>T p.S3= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100524240; called by muse, mutect2, varscan2
- KAT2A | c.1827C>T p.Y609= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs1425857423, COSV99288099; called by muse, mutect2, varscan2
- KCNC2 | c.1866C>T p.N622= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV100128457; called by muse, mutect2, varscan2
- KLHL35 | c.1257C>T p.N419= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1308706964, COSV100888752; called by muse, mutect2, varscan2
- LIMD1 | c.285C>T p.S95= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs143647674, COSV99836846; called by muse, varscan2
- LRP1B | c.1035C>T p.Y345= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs753510633, COSV101254348, COSV67182229, COSV67219512; called by muse, mutect2, varscan2
- MBTD1 | c.714C>T p.S238= | Silent (SNP) | VAF 45/187 reads (24%) | catalogued as rs770734259, COSV100899141; called by muse, mutect2, varscan2
- MCM4 | c.2586G>A p.L862= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100031345; called by muse, mutect2, varscan2
- NINJ1 | c.390G>T p.V130= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100966612; called by muse, mutect2, varscan2
- OR51G2 | c.822C>T p.P274= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs199760109, COSV100432079, COSV100432181; called by muse, mutect2, varscan2
- PATZ1 | c.174G>A p.V58= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99315193; called by muse, mutect2, varscan2
- PCDHA9 | c.1665G>A p.V555= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs781867381, COSV100969247; called by muse, mutect2, varscan2
- PDE4D | c.870G>A p.Q290= (on ENST00000340635 / NM_001104631.2; = p.Q154= on NM_006203.4) | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100505772; called by muse, mutect2, varscan2
- PHIP | c.3555G>A p.V1185= | Silent (SNP) | VAF 11/244 reads (5%) | catalogued as COSV99243671; called by muse, mutect2
- PKIA | c.147G>A p.K49= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100774930; called by muse, mutect2, varscan2
- PLXNC1 | c.309C>T p.S103= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99312673; called by muse, mutect2
- RASSF1 | c.18G>A p.E6= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs750294267, COSV99204696; called by muse, mutect2
- RHBG | c.288G>A p.L96= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99659315; called by muse, mutect2, varscan2
- RPL35A | c.39C>T p.G13= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99502194; called by muse, mutect2, varscan2
- SIGLEC5 | c.957G>A p.P319= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs528680868, COSV55777861; called by muse, mutect2, varscan2
- SLC13A5 | c.450C>T p.P150= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs763748475, COSV99545786; called by muse, mutect2, varscan2
- SLC23A3 | c.579G>A p.G193= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99840961; called by muse, mutect2, varscan2
- SLC9A7 | c.297G>A p.L99= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100091751; called by muse, mutect2, varscan2
- SMARCA5 | c.2542A>C p.R848= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV99303620; called by muse, mutect2, varscan2
- SPRY4 | c.177C>T p.A59= (on ENST00000434127 / NM_001127496.3; = p.A82= on NM_030964.4) | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100702155; called by muse, mutect2, varscan2
- TMSB4X | c.117G>A p.K39= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV101020336; called by mutect2, varscan2
- TNNT1 | c.645C>T p.P215= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1265717493, COSV99402761; called by muse, mutect2, varscan2
- TNRC6C | c.765C>T p.N255= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV56947388; called by muse, mutect2, varscan2
- TRIB1 | c.348G>A p.E116= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100322417; called by muse, mutect2
- UACA | c.2163A>G p.K721= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100537383; called by muse, mutect2, varscan2
- UQCR10 | c.40C>T p.L14= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100340785; called by mutect2, varscan2
- WIF1 | c.48C>T p.S16= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99682684; called by muse, mutect2
- ZMYM2 | c.3315G>A p.K1105= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV101243597; called by muse, mutect2, varscan2
- ZNF534 | c.831T>C p.H277= (on ENST00000332323 / NM_001143939.3; = p.H264= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99989565; called by muse, mutect2, varscan2
- ZNF570 | c.510T>C p.S170= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100356086; called by muse, mutect2, varscan2
- H2AC11 | c.*1C>A | 3'UTR (SNP) | VAF 27/190 reads (14%) | catalogued as COSV100345670; called by muse, mutect2, varscan2
- MIR513A2 | n.14A>T | RNA (SNP) | VAF 120/393 reads (31%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331284 G>C | 5'Flank (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
